Somatic mutation profile of cancer-model specimen HCM-CSHL-0803-C54-85A (3D Organoid, passage 9; aliquot HCM-CSHL-0803-C54-85A-01D-A88H-36), derived from the primary tumor of HCMI case HCM-CSHL-0803-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA.
Specimen HCM-CSHL-0803-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7adfae59-0408-4721-9912-7ade8df1bb1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0803-C54-11A (Solid Tissue Normal), aliquot HCM-CSHL-0803-C54-11A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81d1cfcc-a568-4af8-bd96-a8edc506ea1c

The open-access MAF lists 67 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 16, Nonsense Mutation 4, Frame Shift Del 4, Intron 2, In Frame Del 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 273/552 reads (49%) | catalogued as rs1553159753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 264/264 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.12802G>T p.V4268F | Missense Mutation (SNP) | VAF 277/621 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV60934074; called by muse, mutect2, varscan2
- BCHE | c.1752C>A p.D584E | Missense Mutation (SNP) | VAF 51/242 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1205471724; called by muse, mutect2, varscan2
- CSMD2 | c.8261G>A p.R2754H | Missense Mutation (SNP) | VAF 190/421 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1242987957; called by muse, mutect2, varscan2
- CXXC1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 206/771 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1351909315; called by muse, mutect2, varscan2
- EPG5 | c.6935C>T p.A2312V | Missense Mutation (SNP) | VAF 494/773 reads (64%) | SIFT tolerated (0.22); PolyPhen benign (0.254); catalogued as COSV56345628; called by muse, mutect2, varscan2
- GIT1 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 438/438 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201003587, COSV56613161, COSV99838240; called by muse, mutect2, varscan2
- GPRC6A | c.1428_1430del p.V477del | In Frame Del (DEL) | VAF 89/201 reads (44%) | catalogued as rs747347978; called by pindel, varscan2
- MBD1 | c.309del p.S104Vfs*81 | Frame Shift Del (DEL) | VAF 544/1087 reads (50%) | catalogued as COSV54008080; called by mutect2, pindel, varscan2
- MME | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 122/133 reads (92%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs41267905, COSV64711690; called by muse, mutect2, varscan2
- NIPAL4 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 231/454 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs772226292, COSV61730646; called by muse, mutect2, varscan2
- PTPRZ1 | c.3884C>T p.T1295M | Missense Mutation (SNP) | VAF 150/302 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.244); catalogued as rs746068260, COSV66436120; called by muse, mutect2, varscan2
- REPIN1 | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 25/917 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV68292616; called by muse, mutect2
- RYR2 | c.5291C>T p.S1764F | Missense Mutation (SNP) | VAF 34/674 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV63683165; called by muse, mutect2
- SPDYE3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 176/356 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as rs755303383; called by muse, mutect2, varscan2
- SSX5 | c.69+1G>T p.X23_splice | Splice Site (SNP) | VAF 20/564 reads (4%) | catalogued as COSV61255920, COSV61256754; called by muse, mutect2
- ARHGAP35 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 116/117 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C4orf54 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 157/339 reads (46%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CABIN1 | c.367_412del p.D123Sfs*27 | Frame Shift Del (DEL) | VAF 63/86 reads (73%) | called by mutect2, pindel, varscan2
- CAPN7 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- CD109 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- CELF6 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 351/713 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CHD9 | c.2405C>G p.S802* | Nonsense Mutation (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- COL4A4 | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 166/396 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCC | c.680A>T p.E227V | Missense Mutation (SNP) | VAF 180/529 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- DNAH7 | c.3793G>T p.E1265* | Nonsense Mutation (SNP) | VAF 33/208 reads (16%) | called by mutect2, varscan2
- FOXA2 | c.1042_1055del p.H348Afs*9 (on ENST00000377115 / NM_153675.3; = p.H354Afs*9 on NM_021784.5) | Frame Shift Del (DEL) | VAF 286/662 reads (43%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.224T>C p.V75A | Missense Mutation (SNP) | VAF 16/599 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- GPKOW | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 461/1026 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HELZ2 | c.4020C>G p.F1340L (on ENST00000467148 / NM_001037335.2; = p.F771L on NM_033405.3) | Missense Mutation (SNP) | VAF 514/787 reads (65%) | SIFT tolerated (0.21); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HSPA12B | c.1741G>T p.E581* | Nonsense Mutation (SNP) | VAF 64/1000 reads (6%) | called by muse, mutect2
- HUWE1 | c.5675G>C p.C1892S | Missense Mutation (SNP) | VAF 326/716 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- LAMC2 | c.654G>C p.W218C | Missense Mutation (SNP) | VAF 22/540 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPHOSPH9 | c.2226C>G p.N742K | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MUC12 | c.14525C>G p.P4842R (on ENST00000379442; = p.P4699R on NM_001164462.1) | Missense Mutation (SNP) | VAF 248/492 reads (50%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MUC17 | c.11443T>A p.L3815I | Missense Mutation (SNP) | VAF 27/590 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.621); called by muse, mutect2
- NEU3 | c.271_283del p.L91* | Frame Shift Del (DEL) | VAF 218/504 reads (43%) | called by mutect2, pindel, varscan2
- NFATC2 | c.450G>C p.R150S | Missense Mutation (SNP) | VAF 330/992 reads (33%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NHSL1 | c.420T>A p.F140L | Missense Mutation (SNP) | VAF 23/521 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2
- PIK3AP1 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRTN3 | c.556A>G p.N186D | Missense Mutation (SNP) | VAF 20/512 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); called by muse, mutect2
- SETD1B | c.5472C>A p.F1824L | Missense Mutation (SNP) | VAF 166/330 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRRAP | c.8930G>T p.R2977L (on ENST00000359863 / NM_001244580.1; = p.R2959L on NM_003496.3) | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGT2A1 | c.722C>G p.P241R | Missense Mutation (SNP) | VAF 39/214 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WDFY4 | c.2698C>A p.P900T | Missense Mutation (SNP) | VAF 140/625 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZFHX4 | c.9301C>T p.L3101F | Missense Mutation (SNP) | VAF 32/625 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.436); called by muse, mutect2
- ZNF41 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 28/606 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2
- ADGRL4 | c.1191C>A p.T397= | Silent (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2
- AKAP12 | c.3996C>T p.P1332= | Silent (SNP) | VAF 20/402 reads (5%) | catalogued as rs142473808; called by muse, mutect2
- CASP12 | c.687C>T p.F229= | Silent (SNP) | VAF 23/342 reads (7%) | catalogued as rs1229215437; called by muse, mutect2
- CDH4 | c.342C>T p.D114= | Silent (SNP) | VAF 503/779 reads (65%) | catalogued as rs776377387, COSV64670683; called by muse, mutect2, varscan2
- COL11A1 | c.936A>G p.G312= | Silent (SNP) | VAF 4/100 reads (4%) | called by muse, mutect2
- CSMD1 | c.8991G>T p.L2997= (on ENST00000520002; = p.L2996= on NM_033225.6) | Silent (SNP) | VAF 235/451 reads (52%) | called by muse, mutect2, varscan2
- DRC1 | c.105C>T p.R35= | Silent (SNP) | VAF 36/1072 reads (3%) | called by muse, mutect2
- EPHB1 | c.1764C>G p.S588= | Silent (SNP) | VAF 290/298 reads (97%) | called by muse, mutect2
- FCMR | c.90C>T p.G30= | Silent (SNP) | VAF 241/520 reads (46%) | catalogued as rs756493274; called by muse, mutect2, varscan2
- FICD | c.1227C>T p.G409= | Silent (SNP) | VAF 295/602 reads (49%) | catalogued as rs763816141, COSV57205275, COSV99934078; called by muse, varscan2
- KMT2D | c.9594C>T p.P3198= | Silent (SNP) | VAF 306/620 reads (49%) | called by muse, mutect2, varscan2
- PLEKHF1 | c.48G>A p.A16= | Silent (SNP) | VAF 316/9536 reads (3%) | catalogued as rs1225086239; called by muse, mutect2
- RABGEF1 | c.291C>T p.S97= (on ENST00000439720 / NM_001287061.2; = p.S84= on NM_014504.3 and 29 other RefSeq transcripts) | Silent (SNP) | VAF 38/628 reads (6%) | called by muse, mutect2
- TRPA1 | c.534C>T p.S178= | Silent (SNP) | VAF 71/157 reads (45%) | catalogued as rs771284156, COSV51570133; called by muse, mutect2, varscan2
- UMOD | c.298C>T p.L100= | Silent (SNP) | VAF 44/737 reads (6%) | called by muse, mutect2
- ZYG11A | c.72G>T p.L24= | Silent (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- FBLN1 | c.1698-11269C>T | Intron (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- MARCHF1 | c.242+635C>T | Intron (SNP) | VAF 126/258 reads (49%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227148 C>A | 3'Flank (SNP) | VAF 42/746 reads (6%) | called by muse, mutect2
